MMRF case MMRF_1815 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0f98a79e-5965-47ed-8b58-c586b6d88f01

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 81 years; Vital status: Dead; Days to death: 373 days (1.0 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 81.7 years (29,837 days); ISS stage: III; Days to last known disease status: 373 days (1.0 years); Days to last follow up: 373 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 373.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 2): M Protein 4.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 71.6 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 7.83 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 28 g/L; Total Protein 10.2 g/dL; Glucose 5.34 mmol/L.
- Day 84 (ECOG 2): Hemoglobin 6.57 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 5.6 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -7: Weight: 57 kg; Height: 149 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.

Biospecimens (2 samples)
- Sample MMRF_1815_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_1815_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
